Somatic mutation profile of tumor specimen TCGA-EB-A431-01A (aliquot TCGA-EB-A431-01A-11D-A25O-08) from TCGA case TCGA-EB-A431, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 34.2 years (12,484 days).
Specimen TCGA-EB-A431-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ac99f9f-af04-428a-ad5e-3c8c1fce1539.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A431-10A (Blood Derived Normal), aliquot TCGA-EB-A431-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/683a11d7-3c75-4f4c-8183-4372fea06ab3

The open-access MAF lists 2,086 somatic variants for this specimen: 1,333 protein-altering or splice-affecting, 707 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,238, Silent 707, Nonsense Mutation 62, Splice Region 17, Intron 16, RNA 16, Splice Site 12, 5'UTR 5, 3'Flank 4, 3'UTR 3, 5'Flank 2, In Frame Ins 1.

Variants (750 of 2,086; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVRL1 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565596498, CM050999, COSV66360558; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BCL2L12 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 21/58 reads (36%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.796); catalogued as rs1057519880, COSV55862483; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- OXA1L | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 41/131 reads (31%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.11); PolyPhen benign (0.208); catalogued as rs773412250, COSV53536555; called by muse, mutect2, varscan2
- PPT1 | c.710C>T p.P237L (on ENST00000433473; = p.P238L on NM_000310.4) | Missense Mutation (SNP) | VAF 72/133 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs878853322, CM162438, COSV65655114; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 14/20 reads (70%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1229G>A p.G410E (on ENST00000373993 / NM_138932.2; = p.G402E on NM_014576.4) | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.357); catalogued as COSV50983741, COSV50992038; called by muse, mutect2, varscan2
- A4GALT | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV99966728; called by muse, varscan2
- ABCA1 | c.4433C>T p.P1478L | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs962976305, COSV66068234; called by muse, mutect2, varscan2
- ABCA13 | c.3769C>T p.L1257F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.034); catalogued as COSV101330105, COSV101330145; called by muse, mutect2, varscan2
- ABCA4 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64671698; called by muse, mutect2, varscan2
- ABCA5 | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.983); catalogued as COSV67017817; called by muse, mutect2, varscan2
- ABCA6 | c.4594C>T p.P1532S | Missense Mutation (SNP) | VAF 53/370 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52641279; called by muse, mutect2, varscan2
- ABCA6 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.25); catalogued as COSV52641288; called by muse, mutect2
- ABCA7 | c.4837C>T p.P1613S | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.241); catalogued as COSV54033174; called by muse, mutect2, varscan2
- ABCA8 | c.3643G>A p.D1215N | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52206449; called by muse, mutect2
- ABCA8 | c.1940T>A p.F647Y | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV52206470; called by muse, mutect2, varscan2
- ABCA8 | c.1390C>T p.H464Y | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV52206493; called by muse, mutect2, varscan2
- ABCC3 | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.963); catalogued as COSV53325315; called by muse, mutect2
- ABL1 | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59336058; called by muse, mutect2
- ABL1 | c.2911C>T p.P971S | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV59333318; called by muse, mutect2, varscan2
- ABLIM2 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV56407603; called by muse, mutect2
- ABTB1 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV51742195; called by muse, mutect2, varscan2
- AC004922.1 | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); catalogued as COSV53558011; called by muse, mutect2, varscan2
- AC005833.1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); catalogued as rs781382912, COSV52899187; called by muse, mutect2, varscan2
- AC018755.2 | c.1464+1G>A p.X488_splice | Splice Site (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99707811; called by muse, mutect2, varscan2
- ACAN | c.2698G>A p.D900N | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV61364388; called by muse, mutect2, varscan2
- ACKR2 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 64/119 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs1348293542, COSV56177780; called by muse, mutect2, varscan2
- ACOT12 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56898167; called by muse, mutect2
- ACOT12 | c.925-1G>A p.X309_splice | Splice Site (SNP) | VAF 8/46 reads (17%) | catalogued as rs768762945, COSV100297111; called by muse, mutect2
- ACP3 | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.687); catalogued as COSV60485575; called by muse, mutect2, varscan2
- ACSM4 | c.89G>A p.W30* | Nonsense Mutation (SNP) | VAF 39/167 reads (23%) | catalogued as COSV68068481; called by muse, mutect2, varscan2
- ACSM4 | c.999G>A p.K333= | Splice Region (SNP) | VAF 6/22 reads (27%) | catalogued as COSV68068490; called by muse, mutect2, varscan2
- ACTL6B | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV50514691; called by muse, mutect2, varscan2
- ACTL8 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.556); catalogued as COSV64862002; called by muse, mutect2, varscan2
- ACTRT1 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as COSV64419728; called by muse, mutect2, varscan2
- ADA2 | c.1031C>T p.P344L (on ENST00000262607; = p.P103L on NM_177405.3) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52832327; called by muse, mutect2, varscan2
- ADAM12 | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64104379; called by muse, mutect2, varscan2
- ADAM19 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57434261; called by muse, mutect2, varscan2
- ADAM22 | c.1630G>A p.G544R | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV55982898; called by muse, mutect2, varscan2
- ADAMTS10 | c.1321A>T p.I441F | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54356688; called by muse, mutect2, varscan2
- ADAMTS12 | c.2047G>A p.D683N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.087); catalogued as rs369766198; called by muse, mutect2, varscan2
- ADAMTS16 | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV56986385; called by muse, mutect2, varscan2
- ADAMTS4 | c.432G>A p.W144* | Nonsense Mutation (SNP) | VAF 35/103 reads (34%) | catalogued as COSV63488194; called by muse, mutect2, varscan2
- ADAMTS6 | c.2134G>A p.D712N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs752912116, COSV66861948; called by mutect2, varscan2
- ADAMTS7 | c.3733C>T p.P1245S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV101183209, COSV66306815; called by muse, mutect2
- ADAMTS7 | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs773289537, COSV66308441; called by muse, mutect2, varscan2
- ADAMTS9 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs868112083, COSV55776155; called by muse, mutect2, varscan2
- ADARB2 | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1387809421, COSV67182481; called by muse, mutect2, varscan2
- ADCY6 | c.1717C>T p.R573W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs754674745, COSV57166312; called by muse, mutect2, varscan2
- ADGRA1 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66926341; called by muse, mutect2, varscan2
- ADGRB3 | c.3498G>T p.Q1166H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV53252355; called by muse, mutect2, varscan2
- ADGRD1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs148148477, COSV55450639; called by muse, mutect2, varscan2
- ADGRE1 | c.901C>T p.H301Y | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.472); catalogued as COSV51678185; called by muse, mutect2, varscan2
- ADGRF5 | c.2134C>T p.Q712* | Nonsense Mutation (SNP) | VAF 42/168 reads (25%) | catalogued as COSV51936926; called by muse, mutect2, varscan2
- ADGRG4 | c.4241C>T p.S1414L | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV54950738; called by muse, varscan2
- ADGRG4 | c.6286G>A p.D2096N | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0.19); catalogued as COSV54961462, COSV99796142; called by muse, mutect2, varscan2
- ADGRG4 | c.7835C>T p.S2612L | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV54961470; called by muse, mutect2, varscan2
- ADGRL2 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV54676491; called by muse, mutect2, varscan2
- ADGRL2 | c.3028G>A p.V1010M (on ENST00000370717 / NM_001366005.1; = p.V997M on NM_012302.4) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.34); catalogued as rs1379508714, COSV54676522; called by muse, mutect2, varscan2
- ADGRL3 | c.578C>T p.P193L (on ENST00000506720 / NM_001322402.2; = p.P125L on NM_015236.6) | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV72269604; called by muse, mutect2, varscan2
- ADGRL3 | c.1321G>A p.D441N (on ENST00000506720 / NM_001322402.2; = p.D373N on NM_015236.6) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72268925, COSV72269605; called by muse, mutect2
- ADGRV1 | c.12371C>T p.S4124L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV67989202; called by muse, mutect2
- ADGRV1 | c.13732G>A p.G4578R | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs550190828, COSV67989870; called by muse, mutect2, varscan2
- ADH1A | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV52925537; called by muse, mutect2, varscan2
- ADNP2 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1334380410, COSV51540597; called by muse, mutect2, varscan2
- ADRA1A | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV52369121; called by muse, mutect2, varscan2
- AFF3 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 85/118 reads (72%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as COSV57861863; called by muse, mutect2, varscan2
- AFG1L | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV64556771; called by muse, mutect2, varscan2
- AGO1 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.532); catalogued as COSV64595803; called by muse, mutect2, varscan2
- AGXT2 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 68/101 reads (67%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV51488267; called by muse, mutect2, varscan2
- AKAP9 | c.5356C>T p.L1786F (on ENST00000359028; = p.L1754F on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); catalogued as COSV62351777; called by muse, mutect2, varscan2
- AKNA | c.3815C>T p.P1272L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as rs758599254, COSV56338474; called by muse, mutect2, varscan2
- ALDOB | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as COSV100878912; called by muse, mutect2, varscan2
- ALDOB | c.16C>G p.P6A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.568); catalogued as COSV100878913; called by muse, mutect2, varscan2
- ALX4 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV100240938, COSV61327494; called by muse, varscan2
- AMBN | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774473809, COSV100534483, COSV59827087; called by muse, mutect2, varscan2
- AMBRA1 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.703); catalogued as COSV54047883; called by muse, mutect2, varscan2
- AMDHD2 | c.1174C>T p.Q392* (on ENST00000293971 / NM_001330449.2; = p.Q422* on NM_015944.4) | Nonsense Mutation (SNP) | VAF 73/153 reads (48%) | catalogued as COSV53551527; called by muse, mutect2, varscan2
- AMER3 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774553121, COSV58468223; called by muse, mutect2, varscan2
- AMOTL2 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | catalogued as COSV51439959; called by muse, mutect2, varscan2
- AMPH | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV57749015; called by muse, mutect2, varscan2
- AMPH | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57734569; called by muse, mutect2, varscan2
- ANGPT2 | c.758A>T p.E253V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs990607659, COSV57338531; called by muse, mutect2, varscan2
- ANGPT2 | c.609C>G p.I203M | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV57338550; called by muse, mutect2, varscan2
- ANK3 | c.3910G>A p.E1304K (on ENST00000280772 / NM_001320874.2; = p.E438K on NM_001149.3) | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55068402, COSV99781120; called by muse, mutect2, varscan2
- ANKLE1 | c.1273C>T p.R425* (on ENST00000394458; = p.R371* on NM_152363.6) | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as rs550843607, COSV63920016; called by muse, mutect2, varscan2
- ANKRD11 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99970310; called by muse, mutect2, varscan2
- ANKRD29 | c.430-1G>A p.X144_splice | Splice Site (SNP) | VAF 9/17 reads (53%) | catalogued as rs1260412615, COSV52426755; called by muse, mutect2, varscan2
- ANKRD50 | c.35T>C p.M12T | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.838); catalogued as COSV72385924; called by muse, mutect2, varscan2
- ANKS6 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV100782373; called by muse, mutect2, varscan2
- ANPEP | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1456553395, COSV55589443; called by muse, varscan2
- ANPEP | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55593000; called by muse, mutect2, varscan2
- ANXA10 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.687); catalogued as rs200407221; called by muse, mutect2, varscan2
- AP002512.3 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV54407829; called by muse, mutect2, varscan2
- APOBEC3C | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs368230674, COSV63865410; called by muse, mutect2, varscan2
- APOL3 | c.511C>T p.R171C (on ENST00000349314 / NM_145640.2; = p.R100C on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1229739274, COSV62579232; called by muse, mutect2, varscan2
- AQP9 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as COSV54969601; called by muse, mutect2, varscan2
- ARFGEF1 | c.3847C>T p.H1283Y | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.168); catalogued as COSV51612412; called by muse, mutect2, varscan2
- ARHGAP19 | c.268G>C p.G90R | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.706); catalogued as COSV57393953; called by muse, mutect2, varscan2
- ARHGAP26 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV50834243; called by muse, mutect2, varscan2
- ARHGEF1 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs1288394081, COSV61528629; called by muse, mutect2, varscan2
- ARHGEF10L | c.613T>C p.S205P | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63422466; called by muse, mutect2, varscan2
- ARHGEF10L | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1306978913, COSV51430845; called by muse, mutect2, varscan2
- ARMC9 | c.1519C>G p.L507V | Missense Mutation (SNP) | VAF 71/97 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63022284; called by muse, mutect2, varscan2
- ARNT2 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57591420; called by muse, mutect2, varscan2
- ASAP2 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55634737; called by muse, mutect2, varscan2
- ASB15 | c.700G>A p.G234S | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.401); catalogued as COSV51927591; called by muse, mutect2, varscan2
- ASB16 | c.1270G>A p.G424R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as COSV99519023; called by muse, mutect2, varscan2
- ASB3 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 78/112 reads (70%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV55077581; called by muse, mutect2
- ASB3 | c.295T>A p.L99I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.367); catalogued as COSV55077590; called by muse, mutect2, varscan2
- ASIC3 | c.1439G>A p.R480K | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV52524110; called by muse, mutect2, varscan2
- ASS1 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs761813681, COSV61690018; called by muse, mutect2, varscan2
- ASTN1 | c.2810G>A p.G937E | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100707227, COSV62497623; called by muse, mutect2, varscan2
- ASTN1 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as COSV56076232; called by muse, mutect2, varscan2
- ASTN1 | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56076252; called by muse, mutect2, varscan2
- ATG2A | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV65967589; called by muse, mutect2, varscan2
- ATP10D | c.3976C>T p.P1326S | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV56694872; called by muse, mutect2, varscan2
- ATP11B | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 34/152 reads (22%) | catalogued as rs1423341970, COSV60026312, COSV60030848; called by muse, mutect2, varscan2
- ATP13A4 | c.1543T>C p.F515L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV55065561; called by muse, mutect2, varscan2
- ATP13A5 | c.3553G>A p.G1185R | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.615); catalogued as rs906299367, COSV53232260; called by muse, mutect2, varscan2
- ATP2C1 | c.1559C>A p.A520E | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.258); catalogued as COSV60759090, COSV60761501; called by muse, mutect2, varscan2
- ATRN | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as rs919240372, COSV99497695; called by muse, mutect2, varscan2
- AXIN1 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51983537, COSV51989798; called by muse, mutect2, varscan2
- B3GNTL1 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as rs769610364, COSV57946783; called by muse, mutect2, varscan2
- B4GALNT2 | c.1681C>T p.H561Y | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV55927234; called by muse, mutect2
- BACE2 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.189); catalogued as COSV57741269; called by muse, mutect2, varscan2
- BAG6 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 53/275 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52988769; called by muse, mutect2, varscan2
- BAZ1B | c.239T>G p.F80C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV59992489; called by muse, mutect2, varscan2
- BBS12 | c.1634T>C p.L545S | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58562493; called by muse, mutect2, varscan2
- BCAM | c.1362A>T p.E454D | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV54303563; called by muse, varscan2
- BCAR1 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.986); catalogued as rs1273546100, COSV50790473; called by muse, mutect2, varscan2
- BCL11A | c.1170G>A p.M390I (on ENST00000335712 / NM_001365609.1; = p.M424I on NM_018014.4) | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV59633523; called by muse, mutect2, varscan2
- BCL11B | c.1834G>A p.E612K (on ENST00000357195 / NM_001282237.2; = p.E541K on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1350386971, COSV100596008, COSV61737135; called by muse, mutect2, varscan2
- BCL11B | c.1422G>A p.M474I (on ENST00000357195 / NM_001282237.2; = p.M403I on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61733610; called by muse, mutect2, varscan2
- BCORL1 | c.3247C>T p.R1083W | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs759209893, COSV54400757; called by muse, mutect2, varscan2
- BEX1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as COSV65580392; called by muse, mutect2, varscan2
- BIRC2 | c.1129C>T p.H377Y | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV57162350; called by muse, mutect2, varscan2
- BNIP5 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.123); catalogued as rs781381738, COSV71325496; called by muse, mutect2, varscan2
- BPIFB1 | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs895653462, COSV53607465; called by muse, mutect2
- BPIFB3 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as rs577396258, COSV64957677; called by muse, mutect2, varscan2
- BPIFC | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as COSV55913834; called by muse, mutect2, varscan2
- BRD9 | c.1145T>A p.F382Y | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.815); catalogued as COSV60248132; called by muse, mutect2, varscan2
- BRINP3 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs773859506, COSV66531362; called by muse, mutect2, varscan2
- BRINP3 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs267598250, COSV66527745; called by muse, mutect2, varscan2
- BRPF3 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV60208444; called by muse, mutect2, varscan2
- BSN | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV56516802; called by muse, mutect2, varscan2
- BSN | c.9484G>A p.E3162K | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56522520; called by muse, mutect2, varscan2
- BSN | c.10061C>T p.S3354F | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.858); catalogued as COSV56522529; called by muse, mutect2, varscan2
- BSN | c.11215G>A p.A3739T | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV56522537; called by muse, mutect2, varscan2
- C11orf1 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs151235350, COSV99500205; called by muse, mutect2, varscan2
- C12orf50 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs776851924, COSV53893621; called by muse, mutect2, varscan2
- C12orf56 | c.1205G>A p.R402K (on ENST00000543942 / NM_001170633.2; = p.R242K on NM_001099676.3) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.269); catalogued as COSV61488357; called by muse, mutect2, varscan2
- C14orf180 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59557423; called by muse, mutect2, varscan2
- C1QC | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1373636175, COSV65889544; called by muse, mutect2, varscan2
- C1QTNF12 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as COSV57802980; called by muse, mutect2
- C1RL | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.209); catalogued as COSV56925915; called by muse, mutect2, varscan2
- C1orf127 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV65437971; called by muse, mutect2, varscan2
- C1orf127 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1409627394, COSV65437977; called by muse, mutect2, varscan2
- C4orf50 | c.515C>T p.S172L (on ENST00000324058; = p.S1404L on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.165); catalogued as rs758761959, COSV60689621; called by muse, mutect2, varscan2
- C5orf51 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV67566141; called by muse, mutect2, varscan2
- C6 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV54713386; called by muse, mutect2, varscan2
- C6 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV54713393; called by muse, mutect2, varscan2
- C6orf118 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV57816768; called by muse, mutect2
- C6orf201 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.273); catalogued as COSV60987573; called by muse, mutect2, varscan2
- C8orf34 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61386831; called by muse, mutect2, varscan2
- C9 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs867203884, COSV54678843; called by muse, mutect2
- CA10 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53359308; called by muse, mutect2
- CACNA1B | c.6943C>T p.H2315Y | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.882); catalogued as COSV53136411; called by muse, mutect2, varscan2
- CACNA1D | c.3117G>A p.G1039= (on ENST00000350061 / NM_001128840.3; = p.G1059= on NM_000720.4) | Splice Region (SNP) | VAF 9/19 reads (47%) | catalogued as COSV55455455; called by muse, mutect2, varscan2
- CACNA1F | c.3117A>C p.E1039D | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); catalogued as COSV59905578; called by muse, mutect2, varscan2
- CACNA1I | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60806677; called by muse, mutect2, varscan2
- CACNA1S | c.2743A>G p.K915E | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV62941585; called by muse, mutect2, varscan2
- CACNA2D2 | c.2080G>A p.D694N (on ENST00000479441 / NM_001174051.3; = p.D687N on NM_006030.4) | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as COSV99818190; called by muse, varscan2
- CACNB3 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV56399520; called by muse, mutect2, varscan2
- CACNG3 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.739); catalogued as COSV50074302; called by muse, mutect2, varscan2
- CACNG5 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as COSV50057027, COSV50058773; called by muse, mutect2, varscan2
- CACNG8 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.584); catalogued as COSV54415827; called by muse, mutect2, varscan2
- CADM2 | c.868G>A p.D290N (on ENST00000407528 / NM_001167674.2; = p.D292N on NM_153184.4) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67358866; called by muse, mutect2, varscan2
- CADM3 | c.546T>A p.D182E (on ENST00000368125 / NM_001127173.3; = p.D216E on NM_021189.5) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.9); catalogued as COSV63686329; called by muse, mutect2, varscan2
- CAMK2B | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV51663128, COSV51666013; called by muse, mutect2
- CAMSAP3 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758867421, COSV50341310; called by muse, mutect2, varscan2
- CASD1 | c.890C>A p.P297H | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.999); catalogued as COSV51973833; called by muse, mutect2, varscan2
- CASD1 | c.1964C>T p.S655F | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51973843; called by muse, mutect2, varscan2
- CATSPER4 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.001); catalogued as COSV58793836; called by muse, mutect2, varscan2
- CATSPER4 | c.760C>G p.L254V | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58793844; called by muse, mutect2, varscan2
- CATSPERB | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866512933, COSV56426913; called by muse, mutect2, varscan2
- CAV3 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376624103, COSV57479934; called by muse, mutect2
- CBLN3 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV52162039; called by muse, mutect2, varscan2
- CBX6 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV53321405; called by muse, mutect2
- CCDC102B | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV60144804, COSV60147610; called by muse, mutect2, varscan2
- CCDC178 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV55783892; called by mutect2, varscan2
- CCDC185 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV64821324; called by muse, mutect2, varscan2
- CCDC60 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269666687, COSV59546966; called by muse, varscan2
- CCDC62 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as rs757192126, COSV53433133; called by muse, mutect2, varscan2
- CCDC63 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs776826801, COSV57529444; called by muse, mutect2, varscan2
- CCDC70 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV54430576; called by muse, mutect2, varscan2
- CCL18 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs997360741; called by muse, mutect2, varscan2
- CCNJL | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV57445292; called by muse, mutect2
- CCNT2 | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as rs1447864102, COSV51474662; called by muse, mutect2, varscan2
- CCR8 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58336912; called by muse, mutect2, varscan2
- CD163 | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as rs267603679, COSV63132851; called by muse, mutect2, varscan2
- CD163L1 | c.2518G>A p.D840N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.167); catalogued as COSV58019920; called by muse, mutect2, varscan2
- CD163L1 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV104401769, COSV58019932; called by muse, mutect2, varscan2
- CD2 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs746292283, COSV65644327; called by muse, mutect2, varscan2
- CDC20B | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV57054568; called by muse, mutect2, varscan2
- CDC25C | c.230T>G p.L77R | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV60400347; called by muse, varscan2
- CDC42 | c.197G>A p.R66K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV59662827; called by muse, varscan2
- CDC42BPA | c.188T>G p.F63C | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV62015267; called by muse, mutect2, varscan2
- CDH17 | c.2095C>T p.R699W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs764816423, COSV50325787; called by muse, mutect2, varscan2
- CDH20 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as rs367601432, COSV53005591; called by muse, mutect2, varscan2
- CDH7 | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs369291256; called by muse, mutect2, varscan2
- CDHR1 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV60564357; called by muse, mutect2, varscan2
- CDK1 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as rs1238716954, COSV57349919; called by muse, mutect2, varscan2
- CDK5RAP3 | c.857C>G p.S286C | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV58114883, COSV58115523; called by muse, mutect2, varscan2
- CDX4 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.429); catalogued as COSV65171758; called by muse, mutect2, varscan2
- CEACAM5 | c.702C>T p.L234= | Splice Region (SNP) | VAF 20/67 reads (30%) | catalogued as COSV55753348; called by muse, mutect2, varscan2
- CEACAM7 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV50072923; called by muse, mutect2, varscan2
- CEACAM8 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54991066, COSV54991156; called by muse, mutect2, varscan2
- CEMIP | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV54996180; called by muse, mutect2, varscan2
- CEMIP | c.3044G>A p.R1015Q | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs373796097, COSV54996188; called by muse, mutect2, varscan2
- CEP131 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1363127254, COSV99488869; called by muse, mutect2, varscan2
- CES2 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs1396206702, COSV57696903; called by muse, mutect2, varscan2
- CFAP251 | c.2896C>T p.R966C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.199); catalogued as rs766519266, COSV99996359; called by muse, mutect2, varscan2
- CFAP299 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 5/56 reads (9%) | catalogued as COSV63882354; called by muse, mutect2
- CFAP46 | c.6058G>A p.E2020K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.833); catalogued as COSV54155227; called by muse, mutect2, varscan2
- CFAP46 | c.5629C>T p.L1877F | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs150206082; called by muse, mutect2, varscan2
- CFAP52 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV55346951; called by muse, mutect2, varscan2
- CFTR | c.3994C>T p.P1332S | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV50071178; called by muse, mutect2, varscan2
- CHD4 | c.3163C>T p.R1055C (on ENST00000357008 / NM_001363606.2; = p.R1068C on NM_001273.5) | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58894255; called by muse, mutect2, varscan2
- CHD6 | c.5059C>T p.Q1687* | Nonsense Mutation (SNP) | VAF 20/69 reads (29%) | catalogued as COSV64692568; called by muse, mutect2, varscan2
- CHD9 | c.5959C>T p.L1987F | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV54613086; called by muse, mutect2, varscan2
- CHGB | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100973144, COSV66761055; called by muse, mutect2, varscan2
- CHRNA1 | c.656G>A p.G219E (on ENST00000261007 / NM_001039523.3; = p.G194E on NM_000079.4) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53683999; called by muse, mutect2, varscan2
- CHST1 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1376133529, COSV57322788; called by muse, mutect2, varscan2
- CHST11 | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV57990809; called by muse, mutect2, varscan2
- CHST5 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1365092770, COSV60340401; called by muse, mutect2, varscan2
- CHST8 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV52856837; called by muse, mutect2, varscan2
- CIB1 | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60174612; called by muse, mutect2
- CILK1 | c.1813T>A p.F605I (on ENST00000350082 / NM_001375397.1; = p.F598I on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.159); catalogued as COSV63155138; called by muse, mutect2, varscan2
- CKAP5 | c.5266C>T p.P1756S (on ENST00000529230 / NM_001008938.4; = p.P1696S on NM_014756.3) | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56370656; called by muse, mutect2, varscan2
- CLASP2 | c.2944C>T p.L982F (on ENST00000359576; = p.L981F on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56287295; called by muse, mutect2, varscan2
- CLTCL1 | c.4420G>A p.E1474K | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1137474, COSV54234506; called by muse, mutect2, varscan2
- CLVS1 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57978693; called by muse, mutect2, varscan2
- CLYBL | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59224603; called by muse, mutect2, varscan2
- CMTR2 | c.1390T>G p.F464V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as rs775596139, COSV57603919; called by muse, mutect2, varscan2
- CNKSR3 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.115); catalogued as COSV101401392; called by muse, mutect2, varscan2
- CNST | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 80/126 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV63622124; called by muse, mutect2, varscan2
- CNTN4 | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61876226; called by muse, mutect2, varscan2
- CNTN4 | c.1715G>A p.G572E | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100639803, COSV61876235; called by muse, mutect2, varscan2
- CNTN6 | c.15G>A p.W5* | Nonsense Mutation (SNP) | VAF 26/97 reads (27%) | catalogued as COSV63179998; called by muse, mutect2, varscan2
- CNTN6 | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63180006; called by muse, mutect2, varscan2
- CNTNAP2 | c.3730C>T p.P1244S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV62145718; called by muse, mutect2
- COL11A2 | c.4312G>A p.G1438S (on ENST00000341947 / NM_080680.3; = p.G1331S on NM_080679.2) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59499351; called by muse, mutect2, varscan2
- COL11A2 | c.3953G>A p.G1318E (on ENST00000341947 / NM_080680.3; = p.G1211E on NM_080679.2) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59499362; called by muse, mutect2, varscan2
- COL11A2 | c.2887G>A p.E963K (on ENST00000341947 / NM_080680.3; = p.E856K on NM_080679.2) | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV59499373; called by muse, mutect2, varscan2
- COL14A1 | c.2674G>A p.G892R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1401962365, COSV99920267; called by muse, mutect2, varscan2
- COL14A1 | c.2675G>A p.G892E | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99920268; called by muse, mutect2, varscan2
- COL14A1 | c.4072C>T p.H1358Y | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52860822; called by muse, mutect2, varscan2
- COL14A1 | c.5207G>A p.G1736E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52860832; called by muse, mutect2, varscan2
- COL16A1 | c.2413C>T p.Q805* | Nonsense Mutation (SNP) | VAF 150/482 reads (31%) | catalogued as COSV54703332; called by muse, mutect2, varscan2
- COL19A1 | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs745756517, COSV59578797; called by muse, mutect2
- COL1A1 | c.2386C>T p.R796C | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751890158, COSV56807243; called by muse, mutect2, varscan2
- COL20A1 | c.2330C>T p.P777L | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.35); PolyPhen benign (0.034); catalogued as COSV58921853; called by muse, mutect2, varscan2
- COL22A1 | c.4758G>C p.E1586D | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV57346977; called by muse, mutect2, varscan2
- COL24A1 | c.3364G>A p.G1122R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65302228; called by muse, mutect2, varscan2
- COL24A1 | c.2648C>T p.P883L | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.771); catalogued as rs753030963, COSV65309470; called by muse, mutect2, varscan2
- COL25A1 | c.1198-1G>A p.X400_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV101211722, COSV67649261; called by muse, mutect2, varscan2
- COL27A1 | c.2740G>A p.D914N | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV61928454; called by muse, mutect2
- COL28A1 | c.1687G>A p.G563R | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV68083274; called by muse, mutect2, varscan2
- COL28A1 | c.1064G>A p.G355E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV68081460, COSV68083278; called by muse, mutect2, varscan2
- COL3A1 | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.212); catalogued as COSV58589895, COSV58592894; called by muse, mutect2, varscan2
- COL4A1 | c.4369G>A p.D1457N | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.14); catalogued as COSV65428380; called by muse, mutect2, varscan2
- COL4A4 | c.3728C>T p.P1243L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as COSV100307492; called by muse, mutect2, varscan2
- COL4A4 | c.3727C>T p.P1243S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV61634512; called by muse, mutect2, varscan2
- COL5A2 | c.3208C>T p.R1070C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754429372, COSV66410611; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A2 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs779241228, COSV66411638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A3 | c.4949C>T p.S1650F | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs920250734, COSV53414521; called by muse, mutect2, varscan2
- COL7A1 | c.6340G>A p.G2114S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV60398353; called by muse, mutect2
- COL8A1 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV53729907; called by muse, mutect2
- COL8A1 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53738150; called by muse, mutect2, varscan2
- COL8A1 | c.1063T>A p.F355I | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV99658238; called by muse, mutect2, varscan2
- COL9A2 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1443766012, COSV65607780; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPS5 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV63474939; called by muse, mutect2, varscan2
- COPS5 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as COSV63474475; called by muse, mutect2, varscan2
- CORO1C | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs1371796535, COSV54595477; called by muse, mutect2
- COX4I2 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65781929; called by muse, varscan2
- COX4I2 | c.215G>A p.W72* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV65781931; called by muse, varscan2
- CPAMD8 | c.1807C>T p.L603F (on ENST00000651564; = p.L556F on NM_015692.5) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as COSV52236853; called by muse, mutect2, varscan2
- CPNE4 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV70196930, COSV70197493; called by muse, mutect2, varscan2
- CPPED1 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV55499323; called by muse, mutect2, varscan2
- CPXM2 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV53855569; called by muse, mutect2, varscan2
- CPZ | c.1777C>T p.H593Y (on ENST00000360986 / NM_001014447.3; = p.H582Y on NM_003652.3) | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59923059; called by muse, mutect2, varscan2
- CR1 | c.2710C>T p.P904S | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV65460168; called by muse, mutect2, varscan2
- CR2 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 69/141 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV65508610; called by muse, mutect2, varscan2
- CRACD | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.973); catalogued as rs767474600, COSV51725954; called by muse, mutect2, varscan2
- CRACR2B | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100352129; called by muse, mutect2, varscan2
- CRAMP1 | c.2720C>T p.S907F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51964065, COSV99245600; called by muse, mutect2, varscan2
- CRCT1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | PolyPhen probably damaging (0.998); catalogued as COSV57501005; called by muse, mutect2
- CRKL | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62883744; called by muse, varscan2
- CRYBA4 | c.446G>A p.W149* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV61322443; called by muse, mutect2, varscan2
- CSHL1 | c.457C>T p.Q153* (on ENST00000309894 / NM_022581.3; = p.Q59* on NM_001318.4) | Nonsense Mutation (SNP) | VAF 19/104 reads (18%) | catalogued as COSV51989051; called by muse, varscan2
- CSHL1 | c.448G>A p.E150K (on ENST00000309894 / NM_022581.3; = p.E56K on NM_001318.4) | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51989063; called by muse, varscan2
- CSMD1 | c.6826G>A p.D2276N (on ENST00000520002; = p.D2275N on NM_033225.6) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV59324103; called by muse, mutect2, varscan2
- CSMD1 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV68227675; called by muse, mutect2, varscan2
- CSMD2 | c.9284C>T p.S3095F | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV53921401, COSV53932451; called by muse, mutect2, varscan2
- CSNK1G2 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55337352; called by muse, mutect2, varscan2
- CSRNP1 | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV56189072; called by muse, mutect2, varscan2
- CTAGE1 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66943987; called by muse, mutect2, varscan2
- CTDSPL2 | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as COSV52947152; called by muse, mutect2, varscan2
- CTNNA3 | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65525976, COSV65526515; called by muse, mutect2, varscan2
- CTR9 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748147577, COSV63728467; called by muse, mutect2, varscan2
- CTR9 | c.1348C>A p.P450T | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV63729102; called by muse, mutect2, varscan2
- CUX2 | c.3958G>A p.E1320K | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); catalogued as rs772238149, COSV55628261, COSV55639363; called by muse, mutect2, varscan2
- CWH43 | c.1454A>T p.E485V | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV56941061; called by muse, mutect2, varscan2
- CYP17A1 | c.297+1G>A p.X99_splice | Splice Site (SNP) | VAF 17/55 reads (31%) | catalogued as COSV100882133; called by muse, mutect2, varscan2
- CYP1A2 | c.88G>T p.G30C | Missense Mutation (SNP) | VAF 121/343 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.769); catalogued as rs765154807, COSV59660281; called by muse, mutect2, varscan2
- CYP1A2 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758124536, COSV59659850; called by muse, mutect2, varscan2
- CYP1A2 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.626); catalogued as COSV59660288; called by muse, mutect2, varscan2
- CYP3A7 | c.728G>A p.R243K | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60481238; called by muse, varscan2
- CYP4F8 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV57853859; called by muse, mutect2, varscan2
- CYTH4 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50633938; called by muse, mutect2, varscan2
- CYTIP | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 23/38 reads (61%) | catalogued as rs371815413, COSV51633532; called by muse, mutect2, varscan2
- CYTL1 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV57037249; called by muse, mutect2, varscan2
- DAAM2 | c.1890G>T p.Q630H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV51358436; called by muse, mutect2, varscan2
- DAB2 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); catalogued as COSV57916465; called by muse, mutect2
- DACH1 | c.1840G>A p.G614R (on ENST00000619232 / NM_001366712.1; = p.G360R on NM_004392.6) | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.179); catalogued as COSV57509340; called by muse, mutect2, varscan2
- DACT1 | c.1708C>T p.H570Y | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV60021977; called by muse, mutect2
- DAG1 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated, low confidence (0.51); PolyPhen probably damaging (0.994); catalogued as COSV58185667; called by muse, mutect2, varscan2
- DCAF16 | c.599C>A p.S200Y | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.144); catalogued as COSV66384285; called by muse, mutect2, varscan2
- DCAF4 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1259802858, COSV62318974, COSV62320023; called by muse, mutect2, varscan2
- DCAF4L2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV60480258, COSV60480862; called by muse, mutect2, varscan2
- DCD | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.013); catalogued as COSV53201360, COSV99514082; called by muse, mutect2, varscan2
- DCLK2 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV56207843; called by muse, mutect2, varscan2
- DCP1B | c.1318C>T p.Q440* | Nonsense Mutation (SNP) | VAF 40/107 reads (37%) | catalogued as COSV54970722; called by muse, mutect2, varscan2
- DDX42 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63790661; called by muse, mutect2, varscan2
- DDX60 | c.4198T>A p.F1400I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV67097798; called by muse, mutect2, varscan2
- DEAF1 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs747111818, COSV58607073; called by muse, mutect2, varscan2
- DEFB115 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV68723046; called by muse, mutect2, varscan2
- DENND2B | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV58205622; called by muse, mutect2, varscan2
- DGCR8 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV100708121; called by muse, mutect2, varscan2
- DGKB | c.2278G>A p.G760R | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51800136; called by muse, mutect2, varscan2
- DGKE | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52350518; called by muse, mutect2, varscan2
- DHX9 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.028); catalogued as COSV62360703; called by muse, mutect2, varscan2
- DIP2A | c.4057C>T p.P1353S | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59481927; called by muse, mutect2, varscan2
- DIXDC1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs782005442, COSV59462614; called by muse, mutect2, varscan2
- DKK2 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53400036; called by muse, mutect2, varscan2
- DLG1 | c.166T>A p.Y56N | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV58386775; called by muse, mutect2, varscan2
- DLG5 | c.5135T>C p.F1712S | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs1261359003, COSV64948780; called by muse, mutect2, varscan2
- DLX5 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.164); catalogued as COSV56033589; called by muse, mutect2, varscan2
- DMBT1 | c.3038C>T p.S1013F (on ENST00000338354 / NM_001377530.1; = p.S514F on NM_004406.3) | Missense Mutation (SNP) | VAF 185/415 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.906); catalogued as rs755750716, COSV57541544; called by muse, mutect2, varscan2
- DMBX1 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 68/312 reads (22%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.701); catalogued as COSV63601834; called by muse, mutect2, varscan2
- DMD | c.10768T>A p.L3590I | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58928428, COSV58951587; called by muse, mutect2, varscan2
- DMXL1 | c.7226C>A p.S2409Y | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV60716294; called by muse, mutect2, varscan2
- DNAH10 | c.7871G>A p.R2624Q (on ENST00000409039; = p.R2563Q on NM_207437.3) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs200270614, COSV68996917; called by muse, mutect2
- DNAH3 | c.7860G>A p.E2620= | Splice Region (SNP) | VAF 15/34 reads (44%) | catalogued as COSV54534647; called by muse, mutect2, varscan2
- DNAH5 | c.9790G>A p.D3264N | Missense Mutation (SNP) | VAF 125/321 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.445); catalogued as rs772419948, COSV54238400, COSV54255547; called by muse, mutect2, varscan2
- DNAH5 | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV54238420; called by muse, mutect2, varscan2
- DNAH5 | c.870G>A p.W290* | Nonsense Mutation (SNP) | VAF 57/339 reads (17%) | catalogued as rs916132038, COSV54218105; called by muse, mutect2, varscan2
- DNAH5 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as COSV54226702; called by muse, mutect2, varscan2
- DNAH5 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs779957324, COSV54206424; called by muse, mutect2, varscan2
- DNAH7 | c.10722A>T p.E3574D | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.59); PolyPhen benign (0.102); catalogued as COSV56774215; called by muse, mutect2, varscan2
- DNAH7 | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs534363346, COSV56755548; called by muse, mutect2, varscan2
- DNAH7 | c.2265A>T p.Q755H | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.747); catalogued as COSV100416914; called by muse, mutect2, varscan2
- DNAH8 | c.11287C>T p.L3763F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV59463071; called by muse, mutect2, varscan2
- DNAH9 | c.8830C>T p.R2944W | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs1314819352, COSV52360445; called by muse, mutect2, varscan2
- DNAI4 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV64022640; called by muse, mutect2, varscan2
- DNAJB4 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 28/73 reads (38%) | catalogued as rs141666453, COSV66131887; called by muse, mutect2, varscan2
- DNTT | c.668G>A p.G223D | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1279557945, COSV64523310; called by muse, varscan2
- DOCK4 | c.5590G>A p.G1864S | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.005); catalogued as COSV70240037; called by muse, mutect2, varscan2
- DOCK5 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52406208; called by muse, mutect2, varscan2
- DOCK9 | c.3254C>T p.P1085L (on ENST00000376460 / NM_001366676.2; = p.P1086L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV59635907; called by muse, mutect2, varscan2
- DPPA2 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV72118065; called by muse, mutect2, varscan2
- DPPA3 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as rs1476085353, COSV61502941; called by muse, mutect2, varscan2
- DSC1 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57148231; called by muse, mutect2, varscan2
- DSCAM | c.1763G>A p.S588N | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV68031111; called by muse, varscan2
- DSG1 | c.1472G>A p.R491K | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.85); PolyPhen benign (0.009); catalogued as COSV57137286; called by muse, mutect2, varscan2
- DSG4 | c.2513C>T p.P838L | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV57394276; called by muse, mutect2, varscan2
- DSPP | c.735T>G p.S245R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); catalogued as COSV56813030; called by muse, mutect2, varscan2
- DYSF | c.2884G>A p.G962R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs151064013, COSV50277551; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EARS2 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775975220, COSV54842520; called by muse, mutect2, varscan2
- ECE1 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142918103; called by muse, mutect2, varscan2
- EEF2K | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1362690486, COSV53784253; called by muse, mutect2, varscan2
- EFCAB3 | c.1277G>A p.R426K | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.352); catalogued as rs146706371, COSV59503292; called by muse, mutect2, varscan2
- EFCAB6 | c.2750C>T p.S917L | Missense Mutation (SNP) | VAF 52/399 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs762875526, COSV53067265; called by muse, mutect2, varscan2
- EFNB3 | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56833871; called by muse, mutect2
- EGFL6 | c.1017G>A p.M339I | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV63632904; called by muse, mutect2, varscan2
- EGFLAM | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as COSV59309579; called by muse, mutect2, varscan2
- EGFR | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 86/223 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.036); catalogued as rs1046438724, COSV51778955, COSV51820698; called by muse, mutect2, varscan2
- EIF4G1 | c.4274C>T p.T1425I (on ENST00000346169 / NM_198241.3; = p.T1230I on NM_004953.5) | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.666); catalogued as COSV59992233; called by muse, mutect2, varscan2
- ELAC2 | c.2353C>T p.R785W | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1060502162, COSV52396892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELAVL3 | c.1040G>A p.G347D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99371848; called by muse, mutect2
- ELAVL3 | c.1039G>A p.G347S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52950765; called by muse, mutect2
- ELN | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as COSV52712620; called by muse, mutect2, varscan2
- EME1 | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV56812929; called by muse, mutect2, varscan2
- ENTHD1 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV57322447; called by muse, mutect2, varscan2
- EPPIN | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.666); catalogued as COSV60549111; called by muse, mutect2, varscan2
- EPPK1 | c.1927C>T p.L643F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV73261891; called by muse, mutect2
- EPS8 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV55533508; called by muse, mutect2, varscan2
- EPS8L3 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs555887557, COSV62609790; called by muse, mutect2, varscan2
- EPS8L3 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs755219686, COSV62608679, COSV62609946; called by mutect2, varscan2
- ERBIN | c.2144C>T p.S715L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.057); catalogued as rs760228126, COSV52310795, COSV52329712; called by muse, mutect2, varscan2
- ERC2 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55607947, COSV99888290; called by muse, mutect2, varscan2
- ERC2 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs780679678, COSV55628775; called by muse, mutect2, varscan2
- ERG | c.1129C>T p.R377C (on ENST00000398919 / NM_001243428.1; = p.R353C on NM_004449.4) | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55728586, COSV55738760; called by muse, mutect2, varscan2
- EXOC6 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99592369; called by muse, mutect2, varscan2
- EXOSC10 | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs199634937, COSV58666468; called by muse, mutect2, varscan2
- EYA1 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.069); catalogued as COSV100378743, COSV58167825; called by muse, mutect2, varscan2
- F13A1 | c.1385G>T p.G462V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53562265; called by muse, mutect2, varscan2
- F2RL1 | c.463T>A p.F155I | Missense Mutation (SNP) | VAF 70/319 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56996166; called by muse, mutect2, varscan2
- F5 | c.3968C>T p.P1323L | Missense Mutation (SNP) | VAF 58/317 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.072); catalogued as rs191150742, COSV63125962; called by muse, varscan2
- F5 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63125966; called by muse, mutect2, varscan2
- F8 | c.4690C>T p.P1564S | Missense Mutation (SNP) | VAF 142/183 reads (78%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV64275973; called by muse, mutect2, varscan2
- FAM107A | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.077); catalogued as rs1463110352, COSV62980312; called by muse, mutect2, varscan2
- FAM135B | c.3903G>A p.G1301= | Splice Region (SNP) | VAF 9/41 reads (22%) | catalogued as COSV52738610; called by muse, mutect2, varscan2
- FAM135B | c.3476A>G p.K1159R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs778880625, COSV99426494; called by muse, mutect2, varscan2
- FAM135B | c.1410G>A p.M470I | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52705316; called by muse, mutect2, varscan2
- FAM160A2 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV56409813; called by muse, mutect2, varscan2
- FAM160B1 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.425); catalogued as COSV65088785; called by muse, mutect2, varscan2
- FAM169A | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as rs1268361274, COSV65846886; called by muse, mutect2, varscan2
- FAM171A1 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65317589; called by muse, mutect2, varscan2
- FAM234A | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.925); catalogued as rs779148724, COSV51453265; called by muse, mutect2, varscan2
- FAM3C | c.551T>A p.F184Y | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63436057; called by muse, mutect2, varscan2
- FAM53C | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53512315; called by muse, mutect2, varscan2
- FAM71A | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 20/95 reads (21%) | catalogued as COSV99674847; called by muse, mutect2, varscan2
- FAM71A | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.561); catalogued as COSV54235055; called by muse, mutect2, varscan2
- FAM71B | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.099); catalogued as rs543304286, COSV57229990; called by muse, mutect2, varscan2
- FAM83F | c.1020G>A p.M340I | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV61000675; called by muse, mutect2, varscan2
- FANCI | c.449T>A p.V150E | Missense Mutation (SNP) | VAF 117/181 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55530222; called by muse, mutect2, varscan2
- FARS2 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV51170917; called by muse, mutect2, varscan2
- FASTKD1 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV70007056; called by muse, mutect2, varscan2
- FAT4 | c.2854C>T p.L952F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV67892899; called by muse, mutect2, varscan2
- FAT4 | c.13616C>T p.P4539L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); catalogued as COSV58674769, COSV58688892; called by muse, mutect2, varscan2
- FBN2 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as rs1280198153, COSV52527680; called by muse, mutect2, varscan2
- FBXO22 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1241497731, COSV57618060; called by muse, mutect2, varscan2
- FBXO40 | c.1713T>G p.N571K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV57525689; called by muse, varscan2
- FBXO40 | c.1968A>T p.E656D | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57525709; called by muse, mutect2, varscan2
- FCAR | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 34/102 reads (33%) | catalogued as rs868002531, COSV62030616; called by muse, mutect2, varscan2
- FCAR | c.482A>T p.E161V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV62030629; called by muse, mutect2, varscan2
- FCAR | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62030641; called by mutect2, varscan2
- FCRL5 | c.2060C>T p.S687F | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV62517190, COSV62520714; called by muse, mutect2, varscan2
- FCRLA | c.401C>T p.T134I (on ENST00000367959; = p.T111I on NM_032738.4) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.114); catalogued as COSV99376516; called by muse, mutect2, varscan2
- FER1L6 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs773368685, COSV67551378; called by muse, mutect2, varscan2
- FER1L6 | c.3040C>T p.R1014W | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867750959, COSV67551382; called by muse, mutect2, varscan2
- FES | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 56/790 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.765); catalogued as COSV51578041; called by muse, mutect2
- FGD5 | c.3442G>A p.D1148N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV53247022; called by muse, mutect2
- FGF3 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61926953; called by muse, mutect2, varscan2
- FHDC1 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.634); catalogued as COSV52601371; called by muse, mutect2, varscan2
- FKBP15 | c.1271C>T p.S424L | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV53037038; called by muse, mutect2
- FLNB | c.3398C>T p.P1133L | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV55886107; called by muse, mutect2, varscan2
- FLNB | c.7298A>G p.E2433G | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55886128; called by muse, mutect2, varscan2
- FLNC | c.5722G>A p.D1908N | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1457266502, COSV57959704; called by muse, mutect2, varscan2
- FLRT1 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as COSV55363572; called by muse, mutect2, varscan2
- FLT4 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as COSV56115090; called by muse, mutect2, varscan2
- FMNL2 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV56499087; called by muse, mutect2
- FMOD | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV61610343; called by muse, mutect2, varscan2
- FNDC1 | c.2111G>A p.G704E | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.001); catalogued as COSV51942739; called by muse, mutect2, varscan2
- FOXM1 | c.2057C>T p.S686F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.472); catalogued as COSV61206698; called by muse, mutect2, varscan2
- FOXN1 | c.1027G>A p.G343S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs1340294787, COSV56880820; called by muse, mutect2, varscan2
- FREM2 | c.4402C>T p.H1468Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as COSV54843823; called by muse, mutect2, varscan2
- FRY | c.3692C>T p.S1231F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs866100387, COSV66565485; called by muse, mutect2, varscan2
- FUBP3 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.827); catalogued as COSV60514296, COSV60515190; called by muse, mutect2, varscan2
- FUT3 | c.209G>A p.W70* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as COSV54606977; called by muse, mutect2, varscan2
- FUT5 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267605646, COSV53137446; called by muse, mutect2, varscan2
- FUT9 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as COSV56151021; called by muse, mutect2, varscan2
- GABBR2 | c.1304G>A p.R435K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs146990467; called by muse, mutect2, varscan2
- GABRA2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV100734127, COSV62916787; called by muse, mutect2, varscan2
- GABRQ | c.1630C>T p.L544F | Missense Mutation (SNP) | VAF 56/67 reads (84%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.682); catalogued as rs782113858, COSV64783056; called by muse, mutect2, varscan2
- GAD1 | c.1766G>A p.R589K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV64026716; called by muse, mutect2, varscan2
- GADL1 | c.1033C>T p.L345F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV56981992; called by muse, mutect2, varscan2
- GALNT13 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67213149; called by muse, mutect2, varscan2
- GALNT17 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV61173430; called by muse, mutect2, varscan2
- GALNT17 | c.1301G>A p.R434K | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61169921; called by muse, mutect2, varscan2
- GALNT5 | c.2564G>A p.G855E | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs1255216233, COSV52039234; called by muse, mutect2, varscan2
- GAPVD1 | c.2378T>A p.F793Y | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.878); catalogued as COSV52925095; called by muse, mutect2, varscan2
- GAS2 | c.147G>A p.G49= | Splice Region (SNP) | VAF 18/75 reads (24%) | catalogued as COSV53409722; called by muse, mutect2, varscan2
- GBA3 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs762931123, COSV72438380; called by muse, mutect2, varscan2
- GCKR | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV53109389; called by muse, mutect2, varscan2
- GIMAP5 | c.913C>T p.H305Y | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV57529891; called by muse, mutect2, varscan2
- GLCCI1 | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.978); catalogued as rs1465924986, COSV99780304; called by muse, mutect2, varscan2
- GLI3 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.379); catalogued as COSV101229996; called by muse, mutect2
- GLI3 | c.1180C>A p.P394T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as rs1255889257, COSV101229997; called by muse, mutect2
- GLIS1 | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV56552044; called by muse, mutect2, varscan2
- GLIS1 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV56552053; called by muse, mutect2, varscan2
- GLP2R | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); catalogued as COSV52326728, COSV52326911; called by muse, mutect2, varscan2
- GLYATL2 | c.408A>T p.E136D | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV54850702; called by muse, mutect2, varscan2
- GPATCH2L | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.996); catalogued as rs1332755100, COSV55049718; called by muse, mutect2, varscan2
- GPBP1 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.264); catalogued as rs1173178457, COSV53312922; called by muse, mutect2, varscan2
- GPIHBP1 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.466); catalogued as COSV58209428; called by mutect2, varscan2
- GPLD1 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.025); catalogued as COSV57759248; called by muse, mutect2, varscan2
- GPR108 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV51185678; called by muse, mutect2, varscan2
- GPR158 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199592333, COSV100893624, COSV66276134; called by muse, mutect2, varscan2
- GPR162 | c.1102C>T p.R368C (on ENST00000311268 / NM_019858.2; = p.R84C on NM_014449.2) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs146164363; called by muse, mutect2, varscan2
- GPR171 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV56386699; called by muse, mutect2, varscan2
- GPR176 | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.178); catalogued as COSV54446628; called by muse, mutect2, varscan2
- GPR42 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1274645378, COSV71995062; called by mutect2, varscan2
- GPR83 | c.1229A>T p.K410M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV99703881; called by muse, mutect2, varscan2
- GPRC5C | c.592G>A p.G198S (on ENST00000652232; = p.G153S on NM_018653.4) | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.891); catalogued as COSV61237875; called by muse, mutect2, varscan2
- GPX6 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.86); catalogued as COSV62658176; called by muse, mutect2, varscan2
- GRAMD1C | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1362772324, COSV63983317; called by muse, mutect2, varscan2
- GRAP2 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); catalogued as COSV59996033, COSV59996100; called by muse, mutect2, varscan2
- GRIA1 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53591642; called by muse, mutect2, varscan2
- GRIA1 | c.2570C>T p.S857L | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); catalogued as COSV53612883; called by muse, mutect2, varscan2
- GRIA4 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV56892996, COSV56907493; called by muse, mutect2, varscan2
- GRIK2 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1269034550, COSV59752057; called by muse, mutect2, varscan2
- GRIK3 | c.1877C>T p.S626F | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66142930; called by muse, mutect2, varscan2
- GRIN2A | c.3248A>C p.K1083T | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV58044654; called by muse, mutect2, varscan2
- GRIN3A | c.2642C>T p.S881F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV62456017; called by muse, mutect2, varscan2
- GRIN3A | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV62456132; called by muse, mutect2, varscan2
- GRIP1 | c.2180G>A p.S727N (on ENST00000359742 / NM_001379345.1; = p.S675N on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV54031856; called by muse, mutect2, varscan2
- GRM7 | c.653G>A p.W218* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as COSV63153709; called by muse, mutect2, varscan2
- GRXCR1 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 189/395 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67670838; called by muse, mutect2, varscan2
- GTF3C2 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.084); catalogued as COSV53127730; called by muse, mutect2, varscan2
- HAL | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54118901, COSV99701489; called by muse, mutect2, varscan2
- HAVCR1 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.225); catalogued as rs752404284, COSV59401471; called by mutect2, varscan2
- HBG2 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs151258456, COSV57963441; called by muse, mutect2, varscan2
- HCK | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52944913; called by muse, mutect2, varscan2
- HDHD5 | c.230C>T p.S77F (on ENST00000336737 / NM_033070.3; = p.S47F on NM_017829.5) | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs377264272; called by muse, mutect2, varscan2
- HEATR4 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as COSV100620568; called by muse, mutect2, varscan2
- HEG1 | c.612C>T p.A204= | Splice Region (SNP) | VAF 6/33 reads (18%) | catalogued as rs371723399; called by muse, mutect2
- HEPACAM | c.713G>A p.R238K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV53431111; called by muse, mutect2, varscan2
- HEPACAM | c.55C>G p.P19A | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.039); catalogued as rs767080459, COSV53431123, COSV53433119; called by muse, mutect2, varscan2
- HEXA | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 174/564 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as rs151251788; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HGD | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV52199543; called by muse, mutect2, varscan2
- HIF1A | c.1790G>A p.S597N | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV60190152; called by muse, mutect2, varscan2
- HIP1R | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs755510855, COSV53443006; called by muse, mutect2, varscan2
- HIVEP1 | c.5246C>T p.S1749F | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65101629; called by muse, mutect2, varscan2
- HIVEP3 | c.1226C>T p.T409I | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV56018766; called by muse, mutect2, varscan2
- HJV | c.385C>T p.P129S (on ENST00000336751 / NM_213653.4; = p.P16S on NM_145277.5) | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.378); catalogued as COSV60952554; called by muse, mutect2, varscan2
- HKDC1 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.545); catalogued as COSV63578146; called by muse, mutect2, varscan2
- HKDC1 | c.1824G>A p.M608I | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV63578150; called by muse, mutect2, varscan2
- HLA-DQA2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV66565969; called by muse, varscan2
- HMGB4 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs867842311, COSV53932483; called by muse, mutect2, varscan2
- HMOX1 | c.155C>A p.A52D | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV53340609; called by muse, mutect2, varscan2
- HNMT | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.597); catalogued as rs755441595, COSV54508975; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV54564434; called by muse, mutect2, varscan2
- HOXD10 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs374700658, COSV50901819; ClinVar: likely benign; called by muse, mutect2, varscan2
- HPS6 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV54626195; called by muse, mutect2, varscan2
- HPX | c.302T>A p.F101Y | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56419927; called by muse, mutect2, varscan2
- HR | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.039); catalogued as rs560465295, COSV57193372; called by muse, mutect2, varscan2
- HS6ST2 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.18); catalogued as COSV63715435; called by muse, mutect2, varscan2
- HSD17B12 | c.668A>G p.K223R | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as COSV53501565; called by muse, mutect2, varscan2
- HTR1A | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.615); catalogued as COSV60501806; called by muse, mutect2, varscan2
- HTRA1 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 52/265 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758174014, COSV64564317; called by muse, mutect2, varscan2
- HYDIN | c.4822G>A p.E1608K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs1244006572; called by mutect2, varscan2
- HYDIN | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs866201822, COSV55478832; called by muse, mutect2, varscan2
- IFITM5 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746430875, COSV66888339; called by muse, varscan2
- IFNL2 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as COSV59593783; called by muse, mutect2
- IGHV1OR15-9 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1566869231; called by muse, mutect2, varscan2
- IGHV3-13 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.529); catalogued as rs568429833; called by muse, mutect2, varscan2
- IGHV3-21 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.061); catalogued as rs192949902; called by muse, varscan2
- IGHV3-48 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.196); catalogued as rs371508540; called by mutect2, varscan2
- IGHV3OR16-8 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 79/334 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.874); catalogued as rs772551269; called by muse, mutect2, varscan2
- IGSF10 | c.6758G>A p.R2253K | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.159); catalogued as COSV56386702; called by muse, mutect2, varscan2
- IGSF22 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV60036295; called by muse, mutect2, varscan2
- IL26 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57489453; called by muse, mutect2, varscan2
- IL6ST | c.1427C>T p.T476I | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as COSV61142083; called by muse, mutect2, varscan2
- ILF3 | c.1904C>T p.P635L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); catalogued as rs765854694, COSV51559949; called by muse, mutect2, varscan2
- INAVA | c.483A>T p.E161D | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV66257116; called by muse, mutect2, varscan2
- INF2 | c.3407C>T p.S1136F | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV53034202; called by muse, mutect2, varscan2
- INPP5D | c.619C>T p.P207S (on ENST00000445964 / NM_001017915.3; = p.P206S on NM_005541.5) | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs774932127, COSV64038505; called by muse, mutect2, varscan2
- INSRR | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63875265; called by muse, mutect2, varscan2
- INTS13 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53903993; called by muse, mutect2
- INTS13 | c.1071T>G p.G357= | Splice Region (SNP) | VAF 6/24 reads (25%) | catalogued as rs1565822567, COSV99677547; called by muse, mutect2
- INTS14 | c.427C>T p.P143S (on ENST00000313182 / NM_001366360.2; = p.P64S on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV57527807; called by muse, mutect2, varscan2
- IPPK | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs571708695, COSV55334542; called by muse, mutect2
- IPPK | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV55334759, COSV55335782; called by muse, mutect2
- IQCH | c.1971G>A p.M657I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV60056232; called by muse, mutect2, varscan2
- IQGAP2 | c.4306G>A p.E1436K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.297); catalogued as COSV57177024; called by muse, mutect2, varscan2
- IRF4 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705313; called by muse, mutect2, varscan2
- ISL2 | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs1359244646, COSV51958593, COSV99320786; called by muse, mutect2
- ITGA4 | c.2507C>T p.T836I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.124); catalogued as rs765837614, COSV67898102; called by muse, mutect2, varscan2
- ITGA8 | c.2043A>C p.E681D | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100959583; called by muse, mutect2, varscan2
- ITGA8 | c.2042A>C p.E681A | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100959590; called by muse, mutect2, varscan2
- ITGAL | c.2510C>T p.P837L | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV63323252, COSV63324748; called by muse, mutect2
- ITGAL | c.3022G>A p.D1008N | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV63323257; called by muse, mutect2, varscan2
- ITGB3 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.9); catalogued as COSV71384588; called by muse, mutect2
- ITGB4 | c.3310G>A p.D1104N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV52326441; called by muse, mutect2, varscan2
- ITGB4 | c.4075G>A p.G1359S | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.015); catalogued as rs752995491, COSV52329305; called by muse, mutect2, varscan2
- ITGB6 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51796341; called by muse, mutect2, varscan2
- ITIH3 | c.1069A>T p.K357* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV69649524; called by muse, mutect2, varscan2
- ITK | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.209); catalogued as COSV70063665; called by muse, mutect2, varscan2
- ITSN1 | c.4459C>T p.L1487F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1293814714, COSV67157321; called by muse, mutect2, varscan2
- IVL | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV64216609, COSV64217397; called by muse, mutect2, varscan2
- IZUMO4 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs767681409, COSV61430530; called by muse, mutect2, varscan2
- JCAD | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.234); catalogued as rs747662549, COSV64760640; called by muse, mutect2, varscan2
- JCHAIN | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs1042180308, COSV54659471; called by muse, mutect2, varscan2
- KALRN | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV53765862; called by muse, mutect2, varscan2
- KALRN | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53772362, COSV53773286; called by muse, mutect2, varscan2
- KBTBD12 | c.1631C>T p.S544F | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV59680454; called by muse, mutect2
- KCND1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV54415002; called by muse, mutect2
- KCNH5 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 51/67 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs771677895, COSV59767070; called by muse, mutect2, varscan2
- KCNH7 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV59804210; called by muse, mutect2, varscan2
- KCNH7 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0.101); catalogued as COSV59793012; called by muse, mutect2, varscan2
- KCNN3 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as COSV55221148; called by muse, mutect2, varscan2
- KCNU1 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV67757821; called by muse, mutect2
- KCNU1 | c.993G>A p.K331= | Splice Region (SNP) | VAF 11/33 reads (33%) | catalogued as COSV67757825; called by muse, mutect2, varscan2
- KDM4B | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs536472624, COSV50234788; called by muse, mutect2
- KDM5A | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1362895739, CM118340, COSV66991075; called by muse, mutect2, varscan2
- KDR | c.1881G>A p.M627I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV55770156; called by muse, mutect2, varscan2
- KEL | c.1955G>A p.R652K | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV62336361; called by muse, mutect2, varscan2
- KERA | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57131174; called by muse, mutect2, varscan2
- KIAA0100 | c.5984C>T p.P1995L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56382857; called by muse, mutect2, varscan2
- KIAA0232 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV56923416; called by muse, mutect2, varscan2
- KIAA0586 | c.3143C>T p.P1048L (on ENST00000619416 / NM_001244190.2; = p.P987L on NM_014749.5) | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54178836; called by muse, mutect2, varscan2
- KIAA1210 | c.2792C>T p.S931L | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT deleterious (0.03); PolyPhen benign (0.414); catalogued as COSV68178441; called by muse, mutect2, varscan2
- KIAA1210 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.202); catalogued as COSV68178443; called by muse, mutect2, varscan2
- KIAA1217 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64609044; called by muse, mutect2, varscan2
- KIAA1217 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769073090, COSV56813347; called by muse, mutect2, varscan2
- KIF13A | c.3916G>A p.E1306K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV52457795; called by muse, mutect2, varscan2
- KIF14 | c.4275G>A p.M1425I | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV66262660; called by muse, mutect2, varscan2
- KIF4A | c.3470C>T p.P1157L | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV65533179, COSV65534258; called by muse, mutect2, varscan2
- KIF4B | c.2375C>T p.P792L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV70530346; called by muse, mutect2, varscan2
- KIF7 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1353389253, COSV67998484; called by muse, mutect2, varscan2
- KIFC1 | c.1678C>T p.P560S | Missense Mutation (SNP) | VAF 59/366 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV65729269; called by muse, mutect2, varscan2
- KIR3DL1 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.526); catalogued as rs1436445455, COSV58493239; called by muse, mutect2, varscan2
- KIR3DL1 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.511); catalogued as COSV58488220, COSV58488784; called by muse, mutect2, varscan2
- KL | c.2227C>T p.Q743* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV66309340; called by muse, mutect2, varscan2
- KLF3 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV54711577; called by muse, mutect2, varscan2
- KMO | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as rs1462135407, COSV63805613; called by muse, mutect2, varscan2
- KMT2C | c.9479C>T p.S3160F | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV51466244; called by muse, mutect2, varscan2
- KMT2D | c.12991C>T p.P4331S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.54); PolyPhen probably damaging (0.992); catalogued as COSV56461937; called by muse, mutect2, varscan2
- KPNA3 | c.1249T>G p.C417G | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55505878; called by muse, mutect2, varscan2
- KRT13 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs780908590, COSV55840631; called by muse, mutect2, varscan2
- KRT14 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 84/221 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as COSV51422155; called by muse, mutect2, varscan2
- KRT222 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.998); catalogued as COSV67498620; called by muse, mutect2, varscan2
- KRT33A | c.812A>C p.E271A | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50369914; called by mutect2, varscan2
- KRT34 | c.62G>A p.R21K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV101222514, COSV101222709; called by muse, mutect2, varscan2
- KRT34 | c.61A>T p.R21* | Nonsense Mutation (SNP) | VAF 6/71 reads (8%) | catalogued as COSV101222710; called by muse, mutect2
- KRT36 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV100057729, COSV60203980; called by muse, mutect2, varscan2
- KRT38 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs761233510, COSV55846724; called by mutect2, varscan2
- KRT73 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV59840294; called by muse, mutect2, varscan2
- KRT80 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs370733658; called by muse, mutect2, varscan2
- KRT86 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53293397; called by muse, mutect2, varscan2
- KRTAP10-10 | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 91/205 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59970099; called by muse, mutect2, varscan2
- KRTAP10-4 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs782446212, COSV59967028; called by muse, mutect2, varscan2
- KRTAP12-3 | c.7C>T p.H3Y | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV59970108; called by muse, mutect2, varscan2
- KRTAP5-3 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs571662260, COSV101294499, COSV68790920; called by muse, mutect2, varscan2
- LALBA | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV56396166; called by muse, mutect2, varscan2
- LAMA2 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs778869610, COSV70346902; called by muse, mutect2, varscan2
- LAMA3 | c.4118G>A p.R1373Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs767366608, COSV58073044; called by muse, mutect2, varscan2
- LAMA5 | c.9400C>T p.R3134C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as rs527675374, COSV53364931; called by muse, mutect2, varscan2
- LAMB4 | c.4122+1G>A p.X1374_splice | Splice Site (SNP) | VAF 12/34 reads (35%) | catalogued as COSV52724151; called by muse, mutect2
- LBP | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs374549700, COSV54139002; called by muse, mutect2, varscan2
- LCE3A | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV59550578; called by muse, mutect2, varscan2
- LCTL | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 65/118 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV58422534; called by muse, mutect2, varscan2
- LDLR | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0.021); catalogued as CD003198, CM005337, COSV52944553; called by muse, mutect2, varscan2
- LEPR | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.448); catalogued as COSV60747510, COSV60758963; called by muse, mutect2, varscan2
- LEPR | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1203802094, COSV60758975; called by muse, mutect2, varscan2
- LGALS9B | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770391704, COSV60865486; called by muse, mutect2, varscan2
- LGI2 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs998829213, COSV66122766; called by muse, mutect2, varscan2
- LIF | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV99969949; called by muse, mutect2, varscan2
- LIFR | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.834); catalogued as COSV54693785; called by muse, mutect2, varscan2
- LIFR | c.2337T>C p.G779= | Splice Region (SNP) | VAF 5/50 reads (10%) | catalogued as rs1330946243, COSV54694274; called by muse, mutect2
- LINGO2 | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV58061681; called by muse, mutect2, varscan2
- LMF2 | c.1984C>T p.R662W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs199683816, COSV53318245; called by muse, mutect2
- LMTK3 | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV54314522; called by muse, mutect2, varscan2
- LOXL4 | c.2006G>A p.G669D | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376264431; called by muse, mutect2, varscan2
- LOXL4 | c.2005G>A p.G669S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99583557, COSV99584121; called by muse, mutect2, varscan2
- LPA | c.3676C>T p.P1226S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV60305339; called by muse, mutect2, varscan2
- LPAR1 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.893); catalogued as COSV62688003, COSV62690161; called by muse, mutect2, varscan2
- LRBA | c.5809C>T p.H1937Y | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63959393; called by muse, mutect2, varscan2
- LRBA | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63959397; called by muse, mutect2, varscan2
- LRFN3 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as rs373273430; called by muse, mutect2
- LRIG2 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as rs757114182, COSV63162997; called by muse, mutect2
- LRRC37B | c.1138T>C p.S380P | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.859); catalogued as rs762363996, COSV58953442; called by muse, mutect2, varscan2
- LRRC66 | c.1589G>A p.R530K | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1431212595, COSV58635176; called by muse, mutect2, varscan2
- LRRC8D | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV61577534; called by muse, mutect2, varscan2
- LRRC8D | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61580168; called by muse, mutect2, varscan2
- LRRK2 | c.1802-1G>T p.X601_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | catalogued as COSV54160946; called by muse, mutect2, varscan2
- LRRN2 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV100912932, COSV65784271; called by muse, mutect2, varscan2
- LRTM1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as COSV55540705; called by muse, mutect2, varscan2
- LSG1 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV54569617; called by muse, mutect2, varscan2
- LUC7L3 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 14/112 reads (13%) | catalogued as COSV53588187; called by muse, mutect2, varscan2
- LY96 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs143608308, COSV104373137; called by muse, mutect2, varscan2
- LYPD3 | c.887T>G p.L296W | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.536); catalogued as COSV54989141; called by muse, mutect2, varscan2
- MAGEA1 | c.511C>T p.L171F | Missense Mutation (SNP) | VAF 87/105 reads (83%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as COSV63118442; called by muse, mutect2, varscan2
- MAGEA10 | c.756G>A p.M252I | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT tolerated (0.55); PolyPhen benign (0.03); catalogued as COSV54884837; called by muse, mutect2, varscan2
- MAGEA3 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV64756322; called by muse, mutect2, varscan2
- MAGEC2 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.179); catalogued as COSV56000417; called by muse, mutect2, varscan2
- MAP2K4 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62258869; called by muse, mutect2, varscan2
- MAP3K13 | c.1158G>A p.M386I | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.349); catalogued as rs914886931, COSV53992294; called by muse, mutect2, varscan2
- MAP3K14 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.491); catalogued as rs778366182, COSV60924187; called by muse, mutect2, varscan2
- MAP4K3 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV55715280; called by muse, mutect2, varscan2
- MAPK6 | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.198); catalogued as COSV55930760; called by muse, mutect2, varscan2
- MAPK8 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs773674759, COSV64410106; called by muse, mutect2, varscan2
- MAPT | c.860C>T p.P287L (on ENST00000262410 / NM_001377265.1; = p.P212L on NM_016835.4) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.005); catalogued as rs368295974; called by muse, mutect2, varscan2
- MARCO | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT tolerated (0.07); PolyPhen benign (0.247); catalogued as rs1222641496, COSV59052476; called by muse, mutect2, varscan2
- MAST4 | c.3019C>T p.P1007S (on ENST00000403625 / NM_001164664.2; = p.P818S on NM_015183.3) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.041); catalogued as rs267600670, COSV99845353; called by muse, mutect2, varscan2
- MAST4 | c.3020C>T p.P1007L (on ENST00000403625 / NM_001164664.2; = p.P818L on NM_015183.3) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1379271563, COSV99845356; called by muse, mutect2, varscan2
- MBD3L1 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.04); catalogued as COSV59776008; called by muse, mutect2, varscan2
- MCF2 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as COSV58489401; called by muse, mutect2, varscan2
- MCF2L2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.956); catalogued as COSV61057355; called by muse, mutect2, varscan2
- MCM10 | c.469C>T p.R157W (on ENST00000484800 / NM_182751.3; = p.R156W on NM_018518.5) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs1564381983, COSV66333673; called by muse, mutect2, varscan2
- MCTP2 | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59146570; called by muse, mutect2, varscan2
- MDC1 | c.5350C>T p.H1784Y | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV64525583; called by muse, mutect2, varscan2
- MDGA1 | c.1462G>A p.G488R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51798804; called by muse, mutect2, varscan2
- MECOM | c.1474G>A p.G492R (on ENST00000468789 / NM_001105078.4; = p.G680R on NM_004991.4) | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52968986; called by muse, mutect2, varscan2
- MEI1 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs913004878, COSV55904904; called by muse, mutect2, varscan2
- MEIOC | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV63440603; called by muse, mutect2, varscan2
- METTL17 | c.797T>A p.F266Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV53870441; called by muse, mutect2, varscan2
- MGAM | c.3497C>T p.S1166F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.53); catalogued as rs866572586, COSV72074490; called by muse, mutect2, varscan2
- MGAT5B | c.1724C>T p.S575F (on ENST00000569840 / NM_001199172.2; = p.S573F on NM_144677.3) | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.884); catalogued as COSV56932629; called by muse, mutect2, varscan2
- MGLL | c.43C>T p.P15S (on ENST00000398104 / NM_001003794.2; = p.P25S on NM_007283.6) | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as COSV54027551; called by muse, mutect2, varscan2
- MICALL1 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.141); catalogued as rs748065304, COSV99317500; called by muse, mutect2, varscan2
- MICU1 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV63146114; called by muse, mutect2
- MMP10 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54245739; called by muse, mutect2, varscan2
- MMP28 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as rs749225885; called by muse, mutect2, varscan2
- MNDA | c.987G>A p.K329= | Splice Region (SNP) | VAF 29/79 reads (37%) | catalogued as COSV100933390, COSV63740916; called by muse, mutect2, varscan2
- MOV10L1 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs748360657, COSV53175095; called by muse, mutect2, varscan2
- MPZL3 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as rs1159939466, COSV54053610; called by muse, mutect2, varscan2
- MRC1 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.863); catalogued as rs1342157480; called by muse, mutect2, varscan2
- MROH2B | c.2935A>T p.S979C | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV68186685; called by muse, mutect2, varscan2
- MROH2B | c.2542G>A p.E848K | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.25); PolyPhen benign (0.273); catalogued as rs1208151398, COSV68186691; called by muse, mutect2, varscan2
- MSLNL | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.657); catalogued as COSV53503965; called by muse, mutect2, varscan2
- MTCL1 | c.2225C>T p.P742L (on ENST00000306329 / NM_001378206.1; = p.P382L on NM_015210.4) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.887); catalogued as COSV60405027; called by muse, mutect2, varscan2
- MTOR | c.1924C>T p.H642Y | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.042); catalogued as COSV63874665; called by muse, mutect2, varscan2
- MUC15 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.072); catalogued as COSV55555810, COSV55556013; called by muse, mutect2, varscan2
- MUC16 | c.37574G>A p.G12525E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.995); catalogued as COSV67464394; called by muse, mutect2
- MUC16 | c.28669G>A p.D9557N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.743); catalogued as COSV67478803; called by muse, mutect2, varscan2
- MUC16 | c.19813G>A p.E6605K | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs1452367084, COSV67478819; called by muse, mutect2, varscan2
- MUC16 | c.15789A>T p.K5263N | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.03); catalogued as COSV67478831; called by muse, mutect2, varscan2
- MUC16 | c.13061C>T p.S4354L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV67478836; called by muse, mutect2, varscan2
- MUC16 | c.9161C>T p.S3054L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); catalogued as COSV67448868; called by muse, mutect2, varscan2
- MUC16 | c.8591C>T p.S2864F | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs1354264873, COSV67478848; called by muse, mutect2
- MUC16 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV67451294; called by muse, mutect2, varscan2
- MUC16 | c.1838G>A p.G613E | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); catalogued as COSV67478856; called by muse, mutect2, varscan2
- MUC17 | c.4663C>T p.P1555S | Missense Mutation (SNP) | VAF 74/304 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.959); catalogued as COSV60286271, COSV60295345; called by muse, mutect2, varscan2
- MUC17 | c.5186C>T p.S1729L | Missense Mutation (SNP) | VAF 142/406 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs267601198, COSV60289385; called by muse, mutect2, varscan2
- MUC7 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 57/229 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.53); catalogued as rs1472538687, COSV100512282, COSV100512389, COSV59219352; called by muse, mutect2, varscan2
- MVB12B | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63259289; called by muse, mutect2, varscan2
- MVK | c.649C>T p.H217Y | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV57332430; called by muse, mutect2, varscan2
- MYBPC3 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as rs761079937, COSV57030422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH1 | c.5354G>A p.R1785Q | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs370889656; called by muse, mutect2, varscan2
- MYH1 | c.4966-1G>A p.X1656_splice | Splice Site (SNP) | VAF 17/29 reads (59%) | catalogued as COSV56852396; called by muse, mutect2, varscan2
- MYH1 | c.4295T>C p.L1432P | Missense Mutation (SNP) | VAF 49/71 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56852419; called by muse, mutect2, varscan2
- MYH3 | c.4202C>T p.S1401F | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV56866950; called by muse, mutect2, varscan2
- MYH7B | c.3850G>A p.E1284K | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV52682024; called by muse, mutect2, varscan2
- MYH8 | c.5638T>C p.S1880P | Missense Mutation (SNP) | VAF 78/113 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV67968593; called by muse, mutect2, varscan2
- MYLK | c.5734G>A p.E1912K | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.293); catalogued as COSV60615103; called by muse, mutect2, varscan2
- MYO1B | c.2672C>T p.S891F (on ENST00000304164; = p.S833F on NM_012223.5) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58434188; called by muse, mutect2, varscan2
- MYO7A | c.4111G>A p.V1371M | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV68685667; called by muse, mutect2, varscan2
- MYPN | c.2228C>A p.P743Q | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs138583865, COSV62735747; called by muse, mutect2, varscan2
- MYT1L | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1428261378, COSV67725848; called by muse, mutect2, varscan2
- MZF1 | c.1939C>T p.H647Y | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1270958581, COSV99285404; called by muse, mutect2, varscan2
- NAT2 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54062426; called by muse, mutect2, varscan2
- NAV1 | c.4265G>A p.R1422Q | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as rs750410317, COSV55221282; called by muse, mutect2, varscan2
- NBEA | c.1480C>T p.H494Y | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59782025; called by muse, mutect2, varscan2
- NCOA2 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as COSV71764366; called by muse, mutect2, varscan2
- NDST3 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56623616; called by muse, mutect2, varscan2
1,336 further variants in this file (583 protein-altering or splice-affecting, 707 silent, 46 other) are not listed here.
